Somatic mutation profile of tumor specimen MP2PRT-PAPIBD-TMP1-A (aliquot MP2PRT-PAPIBD-TMP1-A-1-0-D-A83A-36) from MP2PRT case MP2PRT-PAPIBD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 5.9 years (2,142 days).
Specimen MP2PRT-PAPIBD-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c926a178-cb76-4cbb-845c-f3d2190c09b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPIBD-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPIBD-NB1-A-1-0-D-A83A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89e1b085-c0f9-4937-a53f-29034c9eb2da

The open-access MAF lists 16 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 10, Silent 4, Nonsense Mutation 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B3GNT4 | c.74C>A p.A25E | Missense Mutation (SNP) | VAF 147/420 reads (35%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.007); catalogued as rs1424495821, COSV57337331; called by muse, mutect2, varscan2
- CACNA1G | c.3461C>T p.A1154V | Missense Mutation (SNP) | VAF 231/588 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs753357544, COSV61720570; called by muse, mutect2, varscan2
- CHGB | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 95/232 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs144051265; called by muse, mutect2, varscan2
- HDAC4 | c.1720C>T p.R574W | Missense Mutation (SNP) | VAF 236/627 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.394); catalogued as rs201835478, COSV61874189; called by muse, mutect2, varscan2
- MGAT5 | c.1939C>T p.Q647* | Nonsense Mutation (SNP) | VAF 16/535 reads (3%) | catalogued as COSV99924852; called by muse, mutect2
- TSHZ2 | c.2734G>A p.G912R | Missense Mutation (SNP) | VAF 73/456 reads (16%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); catalogued as rs201998606, COSV61586506; called by muse, mutect2, varscan2
- ADGRB1 | c.4732_4734dup p.I1578dup | In Frame Ins (INS) | VAF 117/351 reads (33%) | called by mutect2, varscan2
- CCDC141 | c.1347C>A p.H449Q | Missense Mutation (SNP) | VAF 120/380 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- COL16A1 | c.3235G>A p.D1079N | Missense Mutation (SNP) | VAF 118/401 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- FSIP2 | c.15409A>T p.N5137Y | Missense Mutation (SNP) | VAF 17/289 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2
- KLHL32 | c.752T>A p.V251D | Missense Mutation (SNP) | VAF 142/345 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.193); called by muse, varscan2
- WDR17 | c.3423C>A p.S1141R | Missense Mutation (SNP) | VAF 14/331 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.488); called by muse, mutect2
- GRN | c.75C>T p.F25= | Silent (SNP) | VAF 230/606 reads (38%) | called by muse, varscan2
- IGKV1D-8 | c.352_353insT p.*118L | Silent (INS) | VAF 54/82 reads (66%) | called by mutect2, pindel*, varscan2*
- PCDHA6 | c.1125C>T p.N375= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as rs782536871; called by muse, mutect2, varscan2
- TNK2 | c.1701G>A p.E567= | Silent (SNP) | VAF 297/810 reads (37%) | catalogued as rs200202060; called by muse, mutect2, varscan2
